Somatic mutation profile of tumor specimen TCGA-50-5066-02A (aliquot TCGA-50-5066-02A-11D-2107-08) from TCGA case TCGA-50-5066, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 72.2 years (26,385 days).
Specimen TCGA-50-5066-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7fff37c4-934c-404b-b4a6-00045f08053b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-50-5066-10A (Blood Derived Normal), aliquot TCGA-50-5066-10A-01D-1625-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a97f8364-bf7a-4ba6-aae2-400a226c01b0

The open-access MAF lists 396 somatic variants for this specimen: 307 protein-altering or splice-affecting, 80 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 273, Silent 80, Nonsense Mutation 15, Frame Shift Del 9, Splice Site 6, RNA 4, Intron 3, Splice Region 3, 3'UTR 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.537T>A p.H179Q | Missense Mutation (SNP) | VAF 45/77 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs876660821, CM0910925, COSV52669519, COSV52673406, COSV53016879; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC5 | c.3388G>T p.G1130C | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55596926; called by muse, mutect2, varscan2
- ABCC9 | c.719A>G p.K240R | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV53970002; called by muse, mutect2, varscan2
- ABCD4 | c.1084G>T p.E362* | Nonsense Mutation (SNP) | VAF 45/111 reads (41%) | catalogued as COSV53994684; called by muse, mutect2, varscan2
- ACACB | c.6257G>T p.R2086L | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58133536; called by muse, mutect2, varscan2
- ACTRT1 | c.698G>T p.S233I | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as COSV64419280; called by muse, mutect2, varscan2
- ADAMTS12 | c.1037C>A p.T346N | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61262000; called by muse, mutect2, varscan2
- ADAMTS17 | c.1975G>C p.G659R | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.983); catalogued as COSV51479234, COSV99170439; called by muse, mutect2, varscan2
- ADCY1 | c.1903G>T p.V635L | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52043245; called by muse, mutect2, varscan2
- ADGRE1 | c.1858G>T p.A620S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51681352; called by muse, mutect2, varscan2
- ADH1C | c.75G>T p.E25D | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV72463689; called by muse, mutect2, varscan2
- AGAP3 | c.1013T>G p.I338S (on ENST00000622464; = p.I374S on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV58996533; called by muse, mutect2
- AHNAK2 | c.8857G>C p.A2953P | Missense Mutation (SNP) | VAF 25/279 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV60914417; called by muse, mutect2
- AKAP8L | c.307C>T p.P103S | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV68474764; called by muse, mutect2, varscan2
- AKNA | c.175T>G p.F59V | Missense Mutation (SNP) | VAF 29/37 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56312398; called by muse, mutect2, varscan2
- ALMS1 | c.2587C>G p.L863V | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.51); PolyPhen benign (0.138); catalogued as COSV52508786; called by muse, mutect2, varscan2
- ALPI | c.513G>C p.Q171H | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV55014444; called by muse, mutect2
- ALPK1 | c.2651G>T p.R884M | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV51584570; called by muse, mutect2, varscan2
- AMBRA1 | c.2573C>G p.T858S (on ENST00000458649 / NM_001367468.1; = p.T768S on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.874); catalogued as COSV54063258; called by muse, mutect2, varscan2
- AMFR | c.1097G>C p.R366P | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV51921033; called by muse, mutect2, varscan2
- ANK1 | c.667C>T p.Q223* | Nonsense Mutation (SNP) | VAF 7/24 reads (29%) | catalogued as COSV55880230; called by muse, mutect2
- ANKEF1 | c.952G>T p.A318S | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.054); catalogued as COSV101001019, COSV65692358; called by muse, mutect2, varscan2
- ANKS1B | c.1540G>C p.A514P | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV100248312, COSV61348985; called by muse, mutect2, varscan2
- ARFGEF1 | c.3766G>T p.V1256F | Missense Mutation (SNP) | VAF 52/171 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV51607398; called by muse, mutect2, varscan2
- ARHGAP20 | c.179C>A p.P60H | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.97); catalogued as COSV52819911; called by muse, mutect2, varscan2
- ARHGAP25 | c.845C>T p.P282L (on ENST00000409202 / NM_001007231.3; = p.P274L on NM_014882.3) | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54901794, COSV54904888; called by muse, mutect2, varscan2
- ARHGEF12 | c.4157A>G p.E1386G | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV63104299; called by muse, mutect2, varscan2
- ARPP21 | c.748T>A p.F250I | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.639); catalogued as COSV51796915; called by muse, mutect2, varscan2
- ASAP1 | c.1625A>G p.Y542C | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV63047928; called by muse, mutect2
- ATP1A2 | c.2926C>T p.R976C | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs371742379; called by muse, mutect2, varscan2
- C14orf39 | c.1697T>C p.I566T | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs1305983334, COSV58781539; called by muse, mutect2, varscan2
- C8orf33 | c.458C>G p.P153R | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV58895560; called by muse, mutect2, varscan2
- CACNA1E | c.5660G>A p.R1887K | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.115); catalogued as COSV62429572; called by muse, mutect2
- CAMTA1 | c.3501G>C p.Q1167H | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV57897957; called by muse, mutect2, varscan2
- CASP5 | c.269A>T p.H90L | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.168); catalogued as COSV52828346; called by muse, mutect2, varscan2
- CCDC138 | c.1293G>C p.W431C | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54566666; called by muse, mutect2, varscan2
- CCDC89 | c.16C>T p.L6F | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.044); catalogued as COSV57034972; called by muse, mutect2, varscan2
- CCNB1IP1 | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.047); catalogued as rs1438985746, COSV100738518; called by muse, mutect2, varscan2
- CDH12 | c.1832G>A p.G611E | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101201360, COSV66395997; called by muse, mutect2, varscan2
- CDH18 | c.1529G>C p.S510T | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV56918965; called by muse, mutect2, varscan2
- CDH22 | c.685G>T p.A229S | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.799); catalogued as COSV64839839; called by muse, mutect2, varscan2
- CDH9 | c.398G>T p.R133I | Missense Mutation (SNP) | VAF 55/149 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as COSV50276442, COSV50404628; called by muse, mutect2, varscan2
- CENPE | c.3189A>G p.I1063M | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.188); catalogued as rs775291777, COSV54380594; called by muse, mutect2, varscan2
- CEP85 | c.1973C>T p.P658L | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1316798980, COSV53332888; called by muse, mutect2, varscan2
- CHRNA1 | c.744C>A p.Y248* (on ENST00000261007 / NM_001039523.3; = p.Y223* on NM_000079.4) | Nonsense Mutation (SNP) | VAF 19/107 reads (18%) | catalogued as COSV53685526; called by muse, mutect2, varscan2
- CHTF18 | c.683A>T p.K228M | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV50102662; called by muse, mutect2
- CLBA1 | c.611A>C p.H204P | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV66348587; called by muse, mutect2, varscan2
- CLIC1 | c.701A>T p.E234V | Missense Mutation (SNP) | VAF 38/63 reads (60%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV101007445; called by muse, mutect2, varscan2
- COG6 | c.1166+1G>T p.X389_splice | Splice Site (SNP) | VAF 4/22 reads (18%) | catalogued as COSV62998204; called by muse, mutect2
- COL1A2 | c.937G>T p.G313C | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51955577, COSV51957282; called by muse, mutect2, varscan2
- COL21A1 | c.2541G>C p.L847F | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV55161107, COSV55163176; called by muse, mutect2, varscan2
- COL22A1 | c.632G>T p.G211V | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV57362713; called by muse, mutect2, varscan2
- COL2A1 | c.3814C>A p.P1272T | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61534860; called by muse, mutect2, varscan2
- CPSF1 | c.3637C>T p.H1213Y | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs1198778065, COSV58235764; called by muse, mutect2
- CR2 | c.2024G>C p.G675A | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as COSV100889675, COSV65507413; called by muse, mutect2, varscan2
- CRIM1 | c.2389C>A p.P797T | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54863231; called by muse, mutect2
- CSMD3 | c.9613A>G p.M3205V (on ENST00000297405 / NM_001363185.1; = p.M3036V on NM_052900.3) | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as rs762522299, COSV52331748; called by muse, mutect2, varscan2
- CT55 | c.534A>T p.E178D | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV52277704; called by muse, mutect2
- DACT1 | c.1475G>A p.R492K | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV60020571; called by muse, mutect2, varscan2
- DCLK3 | c.1028G>T p.R343L | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV69363021; called by muse, mutect2, varscan2
- DNAH7 | c.7732A>T p.R2578* | Nonsense Mutation (SNP) | VAF 5/9 reads (56%) | catalogued as COSV56788707; called by muse, mutect2, varscan2
- DNAH9 | c.2439G>T p.E813D | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as COSV52347338; called by muse, mutect2, varscan2
- DNAH9 | c.3468A>C p.K1156N | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as COSV52378786; called by muse, mutect2, varscan2
- DNAJC13 | c.2711G>A p.C904Y | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as rs756197845, COSV53449799; called by muse, mutect2, varscan2
- DOK5 | c.831C>A p.S277R | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); catalogued as COSV52819675, COSV99373540; called by muse, mutect2, varscan2
- DPYS | c.893G>T p.G298V | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV100679362; called by muse, mutect2, varscan2
- DRC7 | c.1348G>A p.A450T | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.291); catalogued as COSV61054366; called by muse, mutect2, varscan2
- DSCAML1 | c.754G>C p.A252P (on ENST00000321322; = p.A192P on NM_020693.4) | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV58389573; called by muse, mutect2, varscan2
- EFCAB5 | c.3082G>A p.E1028K | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV57929284; called by muse, mutect2, varscan2
- EGFR | c.630G>T p.L210= | Splice Region (SNP) | VAF 27/249 reads (11%) | catalogued as COSV51795975; called by muse, mutect2, varscan2
- ELMO2 | c.1182G>T p.E394D | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV51682685; called by muse, mutect2, varscan2
- EML1 | c.1951T>A p.Y651N | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV51744535; called by muse, mutect2, varscan2
- EML5 | c.2540G>T p.G847V | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61345116; called by muse, mutect2, varscan2
- ENPP2 | c.1409T>A p.F470Y (on ENST00000075322 / NM_001040092.3; = p.F522Y on NM_006209.5) | Missense Mutation (SNP) | VAF 24/193 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV50042113; called by muse, mutect2, varscan2
- EPHX2 | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.709); catalogued as COSV66846204; called by muse, mutect2, varscan2
- EPPK1 | c.3952G>T p.G1318W | Missense Mutation (SNP) | VAF 33/175 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV73261122; called by muse, mutect2, varscan2
- EPS15L1 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV50168449; called by muse, varscan2
- FAM120A | c.2246A>T p.Y749F | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.388); catalogued as COSV52904472; called by muse, mutect2, varscan2
- FBXL5 | c.1440G>T p.W480C | Missense Mutation (SNP) | VAF 38/62 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs149921734, COSV58009934; called by muse, mutect2, varscan2
- FBXL5 | c.1319C>G p.S440C | Missense Mutation (SNP) | VAF 57/114 reads (50%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.533); catalogued as COSV58010692; called by muse, mutect2, varscan2
- FER1L6 | c.2095C>G p.Q699E | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV67549660; called by muse, mutect2, varscan2
- FER1L6 | c.4953del p.N1652Tfs*30 | Frame Shift Del (DEL) | VAF 10/68 reads (15%) | catalogued as COSV67548284; called by mutect2, varscan2
- FHOD3 | c.1097C>A p.S366* | Nonsense Mutation (SNP) | VAF 23/61 reads (38%) | catalogued as COSV57163666, COSV57172137; called by muse, mutect2, varscan2
- FIG4 | c.239A>T p.Q80L | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.444); catalogued as COSV57787236; called by muse, mutect2, varscan2
- FLG2 | c.4873G>C p.G1625R | Missense Mutation (SNP) | VAF 53/405 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV66168366; called by muse, mutect2, varscan2
- FLRT2 | c.1741C>G p.R581G | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV58150971; called by muse, mutect2, varscan2
- FRMD8 | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.061); catalogued as rs368973734; called by muse, mutect2, varscan2
- GABRB1 | c.529C>A p.L177M | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752134548, COSV99780572; called by mutect2, varscan2
- GABRR1 | c.727A>G p.I243V | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.361); catalogued as COSV65619322; called by muse, mutect2, varscan2
- GBP4 | c.916+1G>T p.X306_splice | Splice Site (SNP) | VAF 44/77 reads (57%) | catalogued as COSV63254045; called by muse, mutect2, varscan2
- GBP5 | c.410G>C p.G137A | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as COSV58592546; called by muse, mutect2, varscan2
- GCNT1 | c.689T>C p.V230A | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV65057474; called by muse, mutect2, varscan2
- GGH | c.875A>T p.E292V | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52650221; called by muse, mutect2, varscan2
- GIMAP5 | c.103A>C p.K35Q | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57529946; called by muse, mutect2, varscan2
- GNB1L | c.307G>T p.A103S | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.82); PolyPhen benign (0.038); catalogued as COSV61547906, COSV61550112; called by muse, mutect2, varscan2
- GNPTAB | c.818A>T p.N273I | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.529); catalogued as COSV54779370; called by muse, mutect2, varscan2
- GPC5 | c.1576A>T p.M526L | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV65595290; called by muse, mutect2
- GPR22 | c.136G>A p.G46R | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.494); catalogued as rs762775120, COSV51765564; called by muse, varscan2
- GPR85 | c.581T>A p.I194N | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV51783374; called by muse, mutect2, varscan2
- GRIA4 | c.1907C>T p.S636L | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56890545; called by muse, mutect2, varscan2
- GRM6 | c.1590G>T p.M530I | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV51450157; called by muse, mutect2, varscan2
- GSDMA | c.571C>G p.H191D | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.435); catalogued as COSV100053442, COSV100053766, COSV56980106; called by muse, mutect2, varscan2
- GTPBP10 | c.316A>T p.I106L | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.67); PolyPhen benign (0.02); catalogued as COSV55987363; called by muse, mutect2, varscan2
- H2BU1 | c.14C>A p.S5Y | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.069); catalogued as COSV64209567, COSV64209713; called by muse, mutect2, varscan2
- H2BW1 | c.232G>T p.G78W | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as COSV54221621, COSV99474920; called by muse, mutect2, varscan2
- HAO1 | c.1050G>T p.Q350H | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV66491687, COSV66494054, COSV99060335; called by muse, mutect2, varscan2
- HAVCR2 | c.661G>T p.A221S | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.233); catalogued as rs762519713, COSV57152441, COSV57154943; called by muse, mutect2, varscan2
- HBE1 | c.271G>T p.E91* | Nonsense Mutation (SNP) | VAF 49/150 reads (33%) | catalogued as COSV53079958; called by muse, mutect2, varscan2
- HCFC1 | c.3814G>T p.V1272L | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV60071888; called by muse, mutect2, varscan2
- HMCN1 | c.3169G>A p.A1057T | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.458); catalogued as COSV54945073; called by muse, mutect2, varscan2
- HPSE2 | c.460A>T p.S154C | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV65202797; called by muse, mutect2, varscan2
- HTR7 | c.1019G>T p.W340L | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99519173; called by muse, mutect2, varscan2
- IFT172 | c.291A>C p.E97D | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.081); catalogued as rs189236939; called by muse, mutect2, varscan2
- IL1A | c.623C>G p.P208R | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54519497; called by muse, mutect2, varscan2
- INCENP | c.388G>T p.A130S | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV53915264; called by muse, mutect2, varscan2
- IRX2 | c.1082C>T p.A361V | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.08); catalogued as COSV57410982; called by muse, varscan2
- ITIH5 | c.2246A>G p.N749S | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.611); catalogued as COSV53663530; called by muse, mutect2, varscan2
- JPH2 | c.1837G>A p.E613K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.77); PolyPhen benign (0.005); catalogued as rs1354419576, COSV65905852; called by muse, mutect2
- KCNB1 | c.1410G>T p.E470D | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.042); catalogued as COSV65568002; called by muse, varscan2
- KCNH8 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 58/123 reads (47%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.544); catalogued as COSV60462551; called by muse, mutect2, varscan2
- KCNMB1 | c.334A>G p.N112D | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.84); PolyPhen benign (0.103); catalogued as COSV51136520; called by muse, mutect2, varscan2
- KCNT1 | c.61G>T p.G21C | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.917); catalogued as COSV53684255; called by muse, mutect2, varscan2
- KDR | c.3496G>C p.A1166P | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV55764093; called by muse, mutect2, varscan2
- KEAP1 | c.584G>T p.G195V | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV50652758; called by muse, mutect2, varscan2
- KIAA1614 | c.1058A>G p.N353S | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.134); catalogued as COSV62552785; called by muse, mutect2, varscan2
- KIDINS220 | c.3227G>A p.G1076E | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.887); catalogued as COSV56752894; called by muse, mutect2, varscan2
- KIF1A | c.609G>C p.R203S | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57487915; called by muse, mutect2, varscan2
- KLHL36 | c.1457A>G p.H486R | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50724949; called by muse, mutect2, varscan2
- LAMA1 | c.1262-1G>T p.X421_splice | Splice Site (SNP) | VAF 29/57 reads (51%) | catalogued as COSV67544966; called by muse, mutect2, varscan2
- LAMA1 | c.638C>A p.P213H | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV67536268; called by muse, mutect2, varscan2
- LNPK | c.1225G>C p.V409L | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV55823519; called by muse, mutect2, varscan2
- LRFN5 | c.2128G>T p.V710F | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV53254377; called by muse, mutect2, varscan2
- LRRIQ1 | c.2473C>T p.L825F | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67829985; called by muse, mutect2, varscan2
- MAGEC3 | c.196C>A p.L66M | Missense Mutation (SNP) | VAF 26/35 reads (74%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.679); catalogued as COSV53579546; called by muse, varscan2
- MAGEC3 | c.232C>A p.L78I | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV53579553; called by muse, varscan2
- MAPKBP1 | c.1250G>A p.C417Y (on ENST00000456763 / NM_001128608.2; = p.C411Y on NM_014994.3) | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52967339; called by muse, mutect2, varscan2
- MED23 | c.1325A>C p.K442T | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.018); catalogued as COSV63432270; called by muse, mutect2, varscan2
- MGAM | c.1123T>A p.Y375N | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72074545; called by muse, mutect2, varscan2
- MINAR1 | c.2413C>A p.H805N | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.946); catalogued as COSV59587022; called by muse, mutect2, varscan2
- MMP16 | c.980G>A p.R327Q | Missense Mutation (SNP) | VAF 29/190 reads (15%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.552); catalogued as rs146269135; called by muse, mutect2, varscan2
- MORC1 | c.1223T>C p.M408T | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.25); catalogued as COSV51732411; called by muse, mutect2, varscan2
- MPHOSPH10 | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.19); catalogued as COSV54905455, COSV99731168; called by muse, mutect2, varscan2
- MROH7 | c.1657G>A p.E553K | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.143); catalogued as rs368337420; called by muse, mutect2, varscan2
- MXRA5 | c.5541G>T p.W1847C | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV99476086; called by muse, mutect2, varscan2
- MYO5A | c.218A>T p.D73V | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62559693; called by muse, mutect2, varscan2
- NAALAD2 | c.557G>C p.C186S | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as COSV58960595; called by muse, mutect2, varscan2
- NELL1 | c.67G>T p.G23W | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54260371; called by muse, mutect2, varscan2
- NES | c.2060A>T p.E687V | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV100957788; called by muse, mutect2, varscan2
- NES | c.2059G>T p.E687* | Nonsense Mutation (SNP) | VAF 5/14 reads (36%) | catalogued as COSV100957789; called by muse, mutect2, varscan2
- NFKBID | c.145G>C p.G49R (on ENST00000396901; = p.G201R on NM_032721.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 74/113 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61728443; called by muse, mutect2, varscan2
- NKD2 | c.1055C>A p.A352D | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.548); catalogued as COSV99723876; called by muse, mutect2
- NMD3 | c.284T>A p.L95H | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63619752; called by muse, mutect2, varscan2
- NOS2 | c.736G>T p.V246L | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV58227773; called by muse, mutect2, varscan2
- NPAP1 | c.256C>A p.P86T | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV61511820; called by muse, mutect2, varscan2
- NPHP4 | c.3946G>T p.V1316L | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.89); catalogued as COSV65398354; called by muse, varscan2
- NSMAF | c.385-1G>T p.X129_splice | Splice Site (SNP) | VAF 4/52 reads (8%) | catalogued as COSV50702212; called by muse, mutect2
- OBSCN | c.20287A>G p.I6763V | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as COSV63550508; called by muse, mutect2, varscan2
- OR10A3 | c.545C>G p.P182R | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62459253, COSV62460367; called by muse, mutect2, varscan2
- OR10A6 | c.595G>C p.A199P | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV100564250; called by muse, mutect2, varscan2
- OR10J5 | c.34T>G p.F12V | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV58386422; called by muse, mutect2, varscan2
- OR10T2 | c.272A>G p.K91R | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV57783644; called by muse, mutect2, varscan2
- OR13C4 | c.907G>T p.V303L | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV52926469; called by muse, mutect2, varscan2
- OR2F1 | c.467C>A p.S156Y | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101231330, COSV67331559, COSV67332142; called by muse, mutect2, varscan2
- OR2L8 | c.16C>A p.Q6K | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as COSV61728572; called by muse, mutect2, varscan2
- OR2L8 | c.452G>T p.G151V | Missense Mutation (SNP) | VAF 114/378 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV61726598; called by muse, varscan2
- OR2V2 | c.425G>C p.C142S | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV60315494; called by muse, mutect2, varscan2
- OR4C15 | c.736C>A p.H246N (on ENST00000314644; = p.H192N on NM_001001920.2) | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.454); catalogued as COSV58951043, COSV58956031; called by muse, mutect2, varscan2
- OR4C16 | c.347del p.T116Rfs*16 | Frame Shift Del (DEL) | VAF 22/118 reads (19%) | catalogued as COSV58942583; called by mutect2, pindel*, varscan2
- OR4D10 | c.757C>A p.P253T | Missense Mutation (SNP) | VAF 66/270 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770395543, COSV73260019; called by muse, mutect2, varscan2
- OR51S1 | c.221T>C p.L74P | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59058234; called by muse, mutect2, varscan2
- OR52N1 | c.112A>T p.S38C | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV57693276; called by muse, mutect2, varscan2
- OR52N5 | c.239T>A p.L80H | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV57698788; called by muse, mutect2, varscan2
- OR56A4 | c.703A>T p.S235C | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as COSV58111903; called by muse, mutect2, varscan2
- OR5B2 | c.532G>T p.D178Y | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV56909836; called by muse, mutect2, varscan2
- OR8G1 | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.739); catalogued as COSV100422277; called by muse, mutect2, varscan2
- ORM1 | c.305A>T p.E102V | Missense Mutation (SNP) | VAF 61/104 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.148); catalogued as COSV52279276, COSV52279592; called by muse, mutect2, varscan2
- OTOF | c.982C>A p.L328M | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.792); catalogued as COSV99716869; called by muse, mutect2, varscan2
- OVCH1 | c.3140C>A p.P1047Q | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.81); catalogued as rs1457531219, COSV58962263; called by muse, varscan2
- OVCH1 | c.3082A>C p.M1028L | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV58962277; called by muse, varscan2
- PAM | c.932A>T p.N311I | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57220581; called by muse, mutect2, varscan2
- PATJ | c.2494G>T p.D832Y | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV57160996; called by muse, mutect2, varscan2
- PCDH10 | c.2104C>A p.P702T | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as COSV52104765; called by muse, mutect2, varscan2
- PCDH12 | c.1307G>A p.G436E | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774340238, COSV51521121; called by muse, mutect2, varscan2
- PCDHB14 | c.901G>T p.V301F | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.951); catalogued as rs781955583, COSV53388104; called by muse, mutect2
- PCF11 | c.2432G>C p.G811A | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV53538174; called by muse, mutect2, varscan2
- PDE6C | c.1406C>A p.S469Y | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); catalogued as COSV65115050; called by muse, mutect2, varscan2
- PDGFRA | c.213C>G p.I71M | Missense Mutation (SNP) | VAF 59/106 reads (56%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.624); catalogued as COSV57267589; called by muse, mutect2, varscan2
- PGBD5 | c.811A>T p.I271F (on ENST00000525115; = p.I340F on NM_001258311.2) | Missense Mutation (SNP) | VAF 43/67 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV58411421; called by muse, mutect2, varscan2
- PLAG1 | c.1292C>A p.P431H | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.308); catalogued as COSV57610908, COSV57613123; called by muse, mutect2, varscan2
- PLCG2 | c.3353A>T p.E1118V | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV100842110; called by muse, mutect2, varscan2
- PLEKHG3 | c.34A>G p.S12G | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.27); catalogued as COSV55979693; called by muse, mutect2, varscan2
- POF1B | c.1629G>T p.R543S | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.985); catalogued as COSV53133586; called by muse, mutect2, varscan2
- POM121L12 | c.691C>A p.P231T | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV68692849; called by muse, mutect2, varscan2
- PPARGC1A | c.1324A>T p.K442* | Nonsense Mutation (SNP) | VAF 9/21 reads (43%) | catalogued as COSV53527125; called by muse, mutect2, varscan2
- PRDM9 | c.2226C>G p.H742Q | Missense Mutation (SNP) | VAF 56/162 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as COSV57005720; called by muse, varscan2
- PRKCB | c.1805A>T p.Y602F | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV57803421; called by muse, mutect2, varscan2
- PRORP | c.678G>T p.W226C | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51617715, COSV51622397; called by muse, mutect2, varscan2
- PRSS1 | c.89G>A p.C30Y | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61192641; called by muse, varscan2
- PRTG | c.1174A>G p.I392V | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.36); PolyPhen benign (0.074); catalogued as rs376900886; called by muse, mutect2, varscan2
- PSG11 | c.362C>A p.T121N | Missense Mutation (SNP) | VAF 112/210 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1250117363, COSV60454991; called by muse, mutect2, varscan2
- PTAFR | c.859G>C p.V287L | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.065); catalogued as COSV59538466; called by muse, mutect2
- PTPRB | c.4076A>G p.Q1359R | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.101); catalogued as COSV54239495; called by muse, mutect2, varscan2
- PTPRK | c.4210G>C p.V1404L (on ENST00000368215 / NM_001291984.2; = p.V1405L on NM_002844.4) | Missense Mutation (SNP) | VAF 66/129 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as COSV63896468; called by muse, mutect2, varscan2
- PXDNL | c.3340C>T p.P1114S | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.078); catalogued as rs1286186038, COSV62486493; called by muse, mutect2, varscan2
- RALGAPA2 | c.5563G>T p.D1855Y | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV52496079; called by muse, mutect2, varscan2
- RBBP6 | c.4780C>T p.P1594S | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.693); catalogued as COSV60504780; called by muse, mutect2, varscan2
- RBBP8 | c.1471C>G p.L491V | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs561139689, COSV59092266; called by muse, mutect2, varscan2
- RBFOX1 | c.813C>A p.H271Q | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV60985410; called by muse, mutect2, varscan2
- RBM15B | c.1163A>T p.D388V | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV60371819; called by muse, mutect2, varscan2
- RHOT2 | c.1763C>T p.S588F | Missense Mutation (SNP) | VAF 48/144 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.786); catalogued as rs897387617, COSV54808265; called by muse, mutect2, varscan2
- RIMS2 | c.3682G>T p.D1228Y | Missense Mutation (SNP) | VAF 95/198 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51677027, COSV99160151; called by muse, mutect2, varscan2
- RIMS2 | c.4665G>T p.W1555C (on ENST00000666250 / NM_001348490.2; = p.W1126C on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51677034, COSV51681526; called by muse, mutect2, varscan2
- RIMS4 | c.383G>T p.G128V | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV65719131, COSV65719628; called by muse, mutect2, varscan2
- RNF20 | c.776C>T p.T259I | Missense Mutation (SNP) | VAF 43/70 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV66660967; called by muse, mutect2, varscan2
- ROR2 | c.977G>T p.G326V | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as CM1512528, COSV65216770; called by muse, mutect2, varscan2
- RP1 | c.4076C>G p.T1359S | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.049); catalogued as COSV55127954; called by muse, mutect2
- RREB1 | c.1966G>C p.G656R | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV58557102; called by muse, mutect2, varscan2
- RSPO4 | c.132G>T p.E44D | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.95); PolyPhen benign (0.048); catalogued as rs1241980974, COSV54081562; called by muse, mutect2, varscan2
- RTL4 | c.349G>T p.D117Y | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.04); catalogued as COSV61206325; called by muse, mutect2, varscan2
- RTN3 | c.2521G>C p.D841H (on ENST00000377819 / NM_001265589.2; = p.D822H on NM_201428.3) | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as COSV58028396; called by muse, mutect2, varscan2
- SATB2 | c.810G>T p.Q270H | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.526); catalogued as COSV53493240; called by muse, mutect2, varscan2
- SCN9A | c.1736G>T p.G579V | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.457); catalogued as COSV57605175, COSV57626144; called by muse, mutect2, varscan2
- SDK2 | c.3467T>C p.V1156A | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV66185303; called by muse, mutect2, varscan2
- SEPTIN7 | c.440G>T p.R147L | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as COSV63254816; called by muse, mutect2, varscan2
- SERPINA3 | c.111G>T p.E37D | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as COSV67586025; called by muse, mutect2, varscan2
- SH3BP4 | c.1867A>T p.R623W | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60643739; called by muse, mutect2, varscan2
- SI | c.5341C>G p.P1781A | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV52276550; called by muse, mutect2, varscan2
- SIGLEC1 | c.3961G>T p.A1321S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.834); catalogued as COSV99163474; called by muse, varscan2
- SIPA1L1 | c.4512-2A>C p.X1504_splice | Splice Site (SNP) | VAF 8/26 reads (31%) | catalogued as COSV62169870; called by muse, mutect2, varscan2
- SIPA1L2 | c.5111C>A p.T1704K | Missense Mutation (SNP) | VAF 37/59 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV53400894; called by muse, mutect2, varscan2
- SIX4 | c.2038A>G p.M680V | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as rs763418113, COSV53669632, COSV99382023; called by muse, mutect2, varscan2
- SLC11A1 | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs769490777, COSV99261941; called by mutect2, varscan2
- SLC22A1 | c.380A>G p.Y127C | Missense Mutation (SNP) | VAF 31/45 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV61452220; called by muse, mutect2, varscan2
- SLC25A12 | c.311G>C p.G104A | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.242); catalogued as COSV55533129; called by muse, mutect2, varscan2
- SLC2A4RG | c.1151G>T p.R384L | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV55515368, COSV99829511; called by muse, varscan2
- SLC35F1 | c.543C>A p.Y181* | Nonsense Mutation (SNP) | VAF 155/283 reads (55%) | catalogued as COSV64502577, COSV64511796; called by muse, mutect2, varscan2
- SLC35G5 | c.476G>C p.W159S | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV55312556, COSV55315503; called by muse, mutect2, varscan2
- SLC4A3 | c.2732G>C p.R911P | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56093346, COSV56096053; called by muse, mutect2, varscan2
- SLITRK1 | c.908C>A p.S303Y | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.281); catalogued as COSV65677398; called by muse, mutect2, varscan2
- SLITRK2 | c.2043C>A p.D681E | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59425016; called by muse, mutect2, varscan2
- SMCHD1 | c.964G>T p.V322L | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV55269412; called by muse, mutect2, varscan2
- SNTG1 | c.1038+1del | Frame Shift Del (DEL) | VAF 16/87 reads (18%) | catalogued as COSV99384448; called by mutect2, pindel, varscan2
- SPP2 | c.380T>G p.V127G | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV51446829; called by muse, mutect2, varscan2
- ST18 | c.1629T>A p.N543K | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.254); catalogued as COSV52511160; called by muse, mutect2, varscan2
- ST8SIA1 | c.979G>T p.E327* | Nonsense Mutation (SNP) | VAF 23/63 reads (37%) | catalogued as COSV53953557; called by muse, mutect2, varscan2
- STAB2 | c.284A>G p.Y95C | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.511); catalogued as COSV66338394; called by muse, mutect2, varscan2
- STAM2 | c.619G>A p.V207M | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55729697; called by muse, mutect2, varscan2
- STUM | c.261G>T p.R87S | Missense Mutation (SNP) | VAF 138/228 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV64684126; called by muse, mutect2, varscan2
- STX2 | c.50G>C p.G17A | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated (0.47); PolyPhen benign (0.194); catalogued as COSV55433244; called by muse, mutect2, varscan2
- SUGP1 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV53238465; called by muse, mutect2, varscan2
- SYCE2 | c.400C>T p.Q134* | Nonsense Mutation (SNP) | VAF 19/40 reads (48%) | catalogued as COSV53366477; called by muse, mutect2, varscan2
- SYCP1 | c.1836C>A p.N612K | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as COSV65701178; called by muse, mutect2, varscan2
- SYN2 | c.525C>T p.V175= | Splice Region (SNP) | VAF 16/42 reads (38%) | catalogued as COSV70285084; called by muse, mutect2
- SYN2 | c.527G>C p.R176P | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV70285266; called by muse, mutect2
- TAC4 | c.298C>A p.L100M | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.568); catalogued as COSV58004753; called by muse, mutect2, varscan2
- TACR1 | c.928G>A p.D310N | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.364); catalogued as COSV59486696; called by muse, mutect2, varscan2
- TAF4B | c.946C>T p.Q316* | Nonsense Mutation (SNP) | VAF 6/41 reads (15%) | catalogued as COSV52303347; called by muse, mutect2, varscan2
- TBX22 | c.301C>A p.L101M | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1367758632, COSV64787641; called by muse, mutect2, varscan2
- TENM2 | c.7368C>A p.N2456K (on ENST00000518659 / NM_001122679.2; = p.N2217K on NM_001080428.3) | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT deleterious (0.02); PolyPhen benign (0.423); catalogued as COSV69143085; called by muse, mutect2, varscan2
- TENM4 | c.2560G>T p.D854Y | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.274); catalogued as COSV53674201; called by muse, mutect2
- TEX15 | c.4024G>T p.V1342L (on ENST00000256246; = p.V1725L on NM_001350162.2) | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.177); catalogued as COSV56345596; called by muse, mutect2
- TGM4 | c.1481T>G p.L494R | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV56093724; called by muse, mutect2, varscan2
- THSD7A | c.2982C>A p.C994* | Nonsense Mutation (SNP) | VAF 19/199 reads (10%) | catalogued as COSV70264216; called by muse, mutect2
- THSD7B | c.4253C>A p.P1418H (on ENST00000272643; = p.P1416H on NM_001316349.2) | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55702421; called by muse, mutect2, varscan2
- TIMELESS | c.109G>T p.D37Y | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.936); catalogued as rs755484439, COSV57511049, COSV57513109; called by muse, mutect2, varscan2
- TMCO2 | c.116C>T p.T39I | Missense Mutation (SNP) | VAF 47/167 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.408); catalogued as COSV65647052; called by muse, mutect2, varscan2
- TMEM74 | c.151A>G p.R51G | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.747); catalogued as rs1186978087, COSV52463106; called by muse, mutect2, varscan2
- TOGARAM2 | c.1798G>T p.V600L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV65421255; called by muse, mutect2, varscan2
- TPX2 | c.1632C>G p.D544E | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.994); catalogued as COSV55923193; called by mutect2, varscan2
- TRIM56 | c.1322A>T p.Q441L | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.027); catalogued as COSV100047075; called by muse, mutect2, varscan2
- TRPA1 | c.1841A>G p.H614R | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.567); catalogued as COSV51560506; called by muse, mutect2, varscan2
- TRPV3 | c.1481C>A p.A494D | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56796287; called by muse, mutect2, varscan2
- TSHZ2 | c.1477G>A p.D493N | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.081); catalogued as COSV61587607; called by muse, mutect2, varscan2
- TSPAN18 | c.497C>A p.T166N | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV60887916; called by muse, mutect2
- TTC5 | c.1016G>T p.G339V | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV99351628; called by mutect2, varscan2
- TTPA | c.231A>T p.R77S | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52646522; called by mutect2, varscan2
- TULP2 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.044); catalogued as rs1329288025, COSV54386069; called by muse, mutect2, varscan2
- UBAP2 | c.3265-2A>T p.X1089_splice | Splice Site (SNP) | VAF 5/19 reads (26%) | catalogued as COSV99602032; called by muse, mutect2, varscan2
- UBR5 | c.2878G>A p.E960K | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.899); catalogued as COSV55285653; called by muse, mutect2, varscan2
- UMOD | c.181C>A p.L61M | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as COSV56778966; called by muse, mutect2
- UTS2R | c.1090C>G p.P364A | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV57454165; called by muse, mutect2
- VAX1 | c.304A>G p.R102G | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV53331142; called by muse, mutect2, varscan2
- VPS13C | c.1351G>T p.E451* (on ENST00000644861 / NM_020821.3; = p.E408* on NM_017684.5) | Nonsense Mutation (SNP) | VAF 6/13 reads (46%) | catalogued as COSV51426997; called by muse, mutect2, varscan2
- XIRP1 | c.413G>C p.S138T | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.091); catalogued as COSV61141693; called by muse, mutect2, varscan2
- ZIM2 | c.1298C>G p.A433G | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.156); catalogued as COSV55632106, COSV55632367; called by muse, mutect2, varscan2
- ZMIZ2 | c.1559G>T p.R520L | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV54807652; called by muse, mutect2
- ZNF107 | c.737G>T p.C246F | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61332479; called by muse, mutect2
- ZNF16 | c.884G>T p.C295F | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52763490; called by muse, mutect2, varscan2
- ZNF175 | c.1168C>G p.L390V | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.762); catalogued as COSV51798739; called by muse, mutect2, varscan2
- ZNF256 | c.1172G>T p.S391I | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.204); catalogued as COSV99990681; called by muse, mutect2, varscan2
- ZNF488 | c.673C>T p.Q225* | Nonsense Mutation (SNP) | VAF 23/54 reads (43%) | catalogued as rs1310640127; called by muse, mutect2, varscan2
- ZNF594 | c.1447A>G p.T483A | Missense Mutation (SNP) | VAF 25/37 reads (68%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as COSV101280393; called by muse, mutect2, varscan2
- CCL3L3 | c.83C>G p.A28G | Missense Mutation (SNP) | VAF 47/368 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- CLEC14A | c.1320del p.P441Rfs*24 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | called by mutect2, pindel, varscan2
- FLT4 | c.760del p.V254Cfs*42 | Frame Shift Del (DEL) | VAF 8/16 reads (50%) | called by mutect2, pindel*, varscan2
- FMN2 | c.3771del p.Q1258Rfs*17 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | called by mutect2, pindel, varscan2
- HS3ST4 | c.923del p.I308Tfs*16 | Frame Shift Del (DEL) | VAF 10/107 reads (9%) | called by mutect2, varscan2
- HSPA1B | c.*3dup | Frame Shift Ins (INS) | VAF 26/70 reads (37%) | called by mutect2, pindel, varscan2
- IGKV1-16 | c.305C>A p.P102H | Missense Mutation (SNP) | VAF 48/168 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.301); called by muse, varscan2
- IGLV3-27 | c.136C>A p.L46M | Missense Mutation (SNP) | VAF 78/152 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- LINC02877 | n.340C>A | Splice Region (SNP) | VAF 7/12 reads (58%) | called by muse, mutect2, varscan2
- MUC2 | c.3961G>C p.G1321R | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PTPRC | c.1467del p.W489* | Frame Shift Del (DEL) | VAF 23/52 reads (44%) | called by mutect2, pindel, varscan2
- SRCIN1 | c.431A>T p.N144I (on ENST00000621492; = p.N110I on NM_025248.3) | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRBV19 | c.334A>T p.S112C | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- TRBV3-1 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- WDFY3 | c.8554del p.Y2852Ifs*14 | Frame Shift Del (DEL) | VAF 19/39 reads (49%) | called by mutect2, pindel, varscan2
- AC136428.1 | c.237C>T p.Y79= | Silent (SNP) | VAF 39/254 reads (15%) | catalogued as rs369050451; called by muse, mutect2, varscan2
- ADAMTS12 | c.1404C>A p.P468= | Silent (SNP) | VAF 38/93 reads (41%) | catalogued as COSV61261994; called by muse, mutect2, varscan2
- AMZ1 | c.259C>A p.R87= | Silent (SNP) | VAF 111/166 reads (67%) | catalogued as COSV100406267, COSV56686558; called by muse, mutect2, varscan2
- ATP2B1 | c.2619C>T p.G873= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs775895156, COSV53806062; called by muse, mutect2, varscan2
- ATP6V0A4 | c.135C>T p.N45= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as COSV59480972; called by muse, mutect2, varscan2
- AUTS2 | c.1899G>T p.P633= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV61432068; called by muse, mutect2, varscan2
- BPIFB3 | c.30C>T p.S10= | Silent (SNP) | VAF 23/86 reads (27%) | catalogued as COSV64957254; called by muse, mutect2, varscan2
- BRINP1 | c.492G>C p.L164= | Silent (SNP) | VAF 35/63 reads (56%) | catalogued as COSV56298554; called by muse, mutect2, varscan2
- BTN2A2 | c.1089G>A p.E363= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as COSV61858810; called by muse, mutect2, varscan2
- C1R | c.1803G>T p.L601= (on ENST00000536053 / NM_001354346.2; = p.L587= on NM_001733.7) | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as COSV73383059; called by muse, mutect2, varscan2
- CALR | c.390C>T p.I130= | Silent (SNP) | VAF 61/137 reads (45%) | catalogued as COSV100330498; called by muse, mutect2, varscan2
- CAPNS1 | c.426C>T p.D142= | Silent (SNP) | VAF 287/365 reads (79%) | catalogued as COSV55822725; called by muse, mutect2, varscan2
- CHAT | c.1236C>A p.G412= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as rs748510157, COSV60333931; called by muse, mutect2, varscan2
- CSMD3 | c.1629T>C p.C543= (on ENST00000297405 / NM_001363185.1; = p.C439= on NM_052900.3) | Silent (SNP) | VAF 6/95 reads (6%) | catalogued as COSV52331767; called by muse, mutect2
- CTNND2 | c.1266C>G p.P422= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as COSV58885324; called by mutect2, varscan2
- DDX50 | c.1413C>G p.S471= | Silent (SNP) | VAF 12/89 reads (13%) | catalogued as COSV65293444; called by muse, mutect2, varscan2
- DGKQ | c.1800C>G p.L600= | Silent (SNP) | VAF 14/24 reads (58%) | catalogued as rs1254567264, COSV53278572; called by muse, mutect2, varscan2
- DHX33 | c.717C>T p.F239= | Silent (SNP) | VAF 28/158 reads (18%) | catalogued as COSV56578873; called by muse, mutect2, varscan2
- DHX57 | c.3126C>T p.D1042= | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as COSV54884823; called by muse, mutect2, varscan2
- DLK1 | c.270G>A p.R90= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as rs556035501, COSV57993563; called by muse, varscan2
- DOCK2 | c.3339C>T p.D1113= | Silent (SNP) | VAF 40/99 reads (40%) | catalogued as rs1561883407, COSV56955974; called by muse, mutect2, varscan2
- EIF4G3 | c.3159A>C p.L1053= | Silent (SNP) | VAF 24/302 reads (8%) | catalogued as COSV51695170; called by muse, mutect2
- EPHA10 | c.504G>A p.E168= | Silent (SNP) | VAF 25/35 reads (71%) | catalogued as COSV60403164; called by muse, mutect2, varscan2
- FAT2 | c.10833G>T p.T3611= | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as COSV55820591, COSV55830370; called by muse, mutect2, varscan2
- FAT4 | c.4768T>C p.L1590= | Silent (SNP) | VAF 13/114 reads (11%) | catalogued as rs1560757433, COSV67885496; called by muse, mutect2, varscan2
- FBN1 | c.5367C>T p.F1789= | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as COSV57331735; called by muse, mutect2, varscan2
- FRMD8 | c.1035A>T p.T345= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV58214414; called by muse, mutect2
- GABRB1 | c.528C>A p.T176= | Silent (SNP) | VAF 25/48 reads (52%) | catalogued as COSV99780566; called by muse, mutect2, varscan2
- GABRB2 | c.207C>G p.A69= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV50952974; called by muse, mutect2, varscan2
- GCNT1 | c.591C>G p.L197= | Silent (SNP) | VAF 39/77 reads (51%) | catalogued as COSV65057468; called by muse, mutect2, varscan2
- GOLGA3 | c.1815C>A p.T605= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as COSV52630254; called by muse, mutect2, varscan2
- HAVCR2 | c.384C>A p.V128= | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as COSV57154953, COSV57155566; called by muse, mutect2, varscan2
- HIC2 | c.1305G>T p.V435= | Silent (SNP) | VAF 35/210 reads (17%) | catalogued as COSV68042022; called by muse, mutect2, varscan2
- KRTAP5-5 | c.81C>T p.G27= | Silent (SNP) | VAF 18/116 reads (16%) | catalogued as COSV68784848; called by muse, varscan2
- MAMDC4 | c.3096C>T p.P1032= (on ENST00000445819; = p.P953= on NM_206920.3) | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs765293547, COSV56377405, COSV99807921; called by mutect2, varscan2
- MRPL39 | c.459G>A p.V153= | Silent (SNP) | VAF 11/146 reads (8%) | catalogued as COSV56262340; called by muse, mutect2
- MS4A3 | c.6C>T p.A2= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV53935925; called by muse, mutect2, varscan2
- MYH3 | c.3426G>A p.R1142= | Silent (SNP) | VAF 25/44 reads (57%) | catalogued as rs1247849989, COSV56864392; called by muse, mutect2, varscan2
- MYO18B | c.7536C>T p.S2512= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as rs1407996315, COSV59132676; called by muse, mutect2, varscan2
- NCKAP5 | c.3313T>C p.L1105= | Silent (SNP) | VAF 30/207 reads (14%) | catalogued as COSV58436402, COSV58453778; called by muse, mutect2, varscan2
- NID2 | c.1767G>T p.L589= | Silent (SNP) | VAF 48/131 reads (37%) | catalogued as COSV53495858; called by muse, mutect2, varscan2
- NIN | c.6243C>T p.N2081= (on ENST00000382041 / NM_182946.1; = p.N1368= on NM_016350.4) | Silent (SNP) | VAF 36/164 reads (22%) | catalogued as COSV55388737, COSV99815419; called by muse, mutect2, varscan2
- NKD2 | c.1056C>A p.A352= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV99723879; called by muse, mutect2
- NKD2 | c.1182G>A p.S394= | Silent (SNP) | VAF 41/48 reads (85%) | catalogued as rs1421705805, COSV56891360; called by muse, mutect2, varscan2
- NLRP4 | c.763C>A p.R255= | Silent (SNP) | VAF 42/88 reads (48%) | catalogued as COSV56712737, COSV56721500; called by muse, mutect2, varscan2
- NPBWR2 | c.474C>G p.R158= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV63900648; called by muse, mutect2, varscan2
- NRN1L | c.162C>T p.I54= | Silent (SNP) | VAF 50/114 reads (44%) | catalogued as COSV59302635; called by muse, mutect2, varscan2
- NRXN3 | c.1302C>A p.G434= (on ENST00000335750 / NM_001330195.2; = p.G61= on NM_004796.6) | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as COSV59710548, COSV59743312; called by muse, mutect2, varscan2
- NUDT7 | c.393C>T p.N131= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV99215967; called by muse, mutect2, varscan2
- OR11A1 | c.447C>A p.T149= | Silent (SNP) | VAF 57/90 reads (63%) | catalogued as COSV65820905; called by muse, mutect2, varscan2
- OR2G6 | c.273C>A p.T91= | Silent (SNP) | VAF 72/184 reads (39%) | catalogued as COSV100598052, COSV58575338; called by muse, mutect2, varscan2
- OR2L8 | c.864C>A p.I288= | Silent (SNP) | VAF 54/332 reads (16%) | catalogued as COSV61728431; called by muse, varscan2
- OR2M2 | c.93C>A p.V31= | Silent (SNP) | VAF 120/187 reads (64%) | catalogued as COSV62897748, COSV62898239; called by muse, mutect2, varscan2
- OR51S1 | c.81C>A p.G27= | Silent (SNP) | VAF 46/108 reads (43%) | catalogued as COSV59058250; called by muse, mutect2, varscan2
- OR5T3 | c.585T>A p.P195= | Silent (SNP) | VAF 39/169 reads (23%) | catalogued as COSV57380389; called by muse, mutect2, varscan2
- OR8G1 | c.630C>G p.P210= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV100422278; called by muse, mutect2, varscan2
- PAIP1 | c.342T>A p.A114= | Silent (SNP) | VAF 32/311 reads (10%) | catalogued as COSV59087976; called by muse, mutect2, varscan2
- PAPPA2 | c.1716C>A p.V572= | Silent (SNP) | VAF 79/135 reads (59%) | catalogued as COSV100866860, COSV62777448; called by muse, mutect2, varscan2
- PKP2 | c.99C>A p.P33= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV50730007; called by muse, varscan2
- PPFIA4 | c.1887C>A p.T629= (on ENST00000447715; = p.T630= on NM_001304331.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV55322171; called by muse, mutect2, varscan2
- PPP1R26 | c.1068G>A p.A356= | Silent (SNP) | VAF 25/71 reads (35%) | catalogued as rs201948964, COSV63357512; called by muse, mutect2, varscan2
- PRAMEF14 | c.132C>T p.F44= | Silent (SNP) | VAF 32/68 reads (47%) | called by muse, varscan2
- PRPS1L1 | c.312G>T p.R104= | Silent (SNP) | VAF 10/142 reads (7%) | catalogued as rs1243527117, COSV72650028; called by muse, mutect2
- PSG9 | c.1146C>A p.P382= | Silent (SNP) | VAF 38/107 reads (36%) | catalogued as COSV52484787, COSV99392220; called by muse, mutect2, varscan2
- SERGEF | c.210C>T p.L70= | Silent (SNP) | VAF 24/140 reads (17%) | catalogued as rs748353093, COSV56383089; called by muse, mutect2, varscan2
- SESTD1 | c.516A>G p.S172= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as rs1384498727, COSV58931078; called by muse, mutect2, varscan2
- SFTPB | c.801C>T p.P267= | Silent (SNP) | VAF 17/27 reads (63%) | catalogued as rs565870876, COSV60894562; called by muse, mutect2, varscan2
- SGIP1 | c.162A>G p.K54= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV52779798; called by muse, mutect2, varscan2
- SLC15A1 | c.1962G>A p.A654= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs143994270; called by mutect2, varscan2
- SLC30A8 | c.486A>C p.A162= | Silent (SNP) | VAF 22/220 reads (10%) | catalogued as rs756406161, COSV69976734; called by muse, mutect2
- SPRED2 | c.960G>A p.E320= | Silent (SNP) | VAF 29/211 reads (14%) | catalogued as rs1387447866, COSV62692685; called by muse, mutect2, varscan2
- SPTB | c.5175G>T p.V1725= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV67635345; called by muse, mutect2, varscan2
- TDP1 | c.675G>T p.L225= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV59643092; called by muse, mutect2, varscan2
- TECRL | c.432C>A p.T144= | Silent (SNP) | VAF 26/52 reads (50%) | catalogued as COSV67086832, COSV67090948; called by muse, mutect2, varscan2
- TFAP2D | c.363G>T p.A121= | Silent (SNP) | VAF 66/99 reads (67%) | catalogued as rs1359834659, COSV50408145, COSV50414800; called by muse, mutect2, varscan2
- TMPRSS11D | c.570C>A p.G190= | Silent (SNP) | VAF 103/176 reads (59%) | catalogued as COSV52222980; called by muse, mutect2, varscan2
- URB2 | c.3498A>C p.P1166= | Silent (SNP) | VAF 26/50 reads (52%) | catalogued as COSV50987290; called by muse, mutect2, varscan2
- VPS36 | c.324C>G p.L108= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV65199059; called by muse, mutect2, varscan2
- ZNF595 | c.1626C>A p.G542= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV59554234; called by muse, mutect2, varscan2
- ZNF709 | c.1584G>T p.G528= | Silent (SNP) | VAF 26/70 reads (37%) | catalogued as COSV67194188, COSV67194655; called by muse, mutect2, varscan2
- ABL2 | c.158-9668G>T | Intron (SNP) | VAF 26/50 reads (52%) | catalogued as COSV100772554; called by muse, mutect2, varscan2
- ARNT2 | c.*3517C>A | 3'UTR (SNP) | VAF 51/144 reads (35%) | catalogued as COSV100308703; called by muse, mutect2, varscan2
- BCL2L14 | c.679-102C>T | Intron (SNP) | VAF 8/50 reads (16%) | catalogued as rs749896783, COSV53784079; called by mutect2, varscan2
- FAM86C1P | n.266C>A | RNA (SNP) | VAF 9/72 reads (13%) | catalogued as COSV60642297; called by muse, mutect2, varscan2
- LINC02843 | n.419T>C | RNA (SNP) | VAF 29/44 reads (66%) | catalogued as rs376284170; called by muse, mutect2, varscan2
- MGAM | c.4618+10745C>A | Intron (SNP) | VAF 14/73 reads (19%) | catalogued as COSV101527411; called by muse, mutect2, varscan2
- RSPH14 | c.*2C>T | 3'UTR (SNP) | VAF 47/126 reads (37%) | catalogued as COSV99320523; called by muse, mutect2, varscan2
- SNORD116-2 | n.34T>C | RNA (SNP) | VAF 14/148 reads (9%) | called by muse, mutect2
- SSPOP | n.15269G>T | RNA (SNP) | VAF 17/48 reads (35%) | catalogued as COSV65129521, COSV65135239; called by muse, mutect2, varscan2
